Somatic mutation profile of tumor specimen TCGA-AB-2863-03B (aliquot TCGA-AB-2863-03B-01W-0728-08) from TCGA case TCGA-AB-2863, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,132 days).
Specimen TCGA-AB-2863-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09ce21c9-a36c-49ce-802a-46941860d70f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2863-11B (Solid Tissue Normal), aliquot TCGA-AB-2863-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/511258a9-da1a-42eb-8a35-b45c9942cf56

The open-access MAF lists 650 somatic variants for this specimen: 520 protein-altering or splice-affecting, 122 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 391, Silent 122, Frame Shift Ins 69, Nonsense Mutation 32, Frame Shift Del 20, Splice Region 4, Splice Site 4, Intron 3, 5'Flank 2, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAH | c.1099dup p.L367Pfs*27 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs62506951; ClinVar: not provided / likely pathogenic / pathogenic; called by pindel, varscan2
- ABCA9 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60622946; called by muse, mutect2, varscan2
- AKAP3 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs893921051; called by muse, mutect2
- ALDH1A2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs754006072; called by muse, varscan2
- AMOT | c.2218C>T p.R740C (on ENST00000371959 / NM_001113490.1; = p.R331C on NM_133265.3) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1217757912, COSV59065415; called by muse, mutect2
- ANAPC16 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100192110; called by muse, mutect2, varscan2
- ARHGAP24 | c.1883A>T p.D628V (on ENST00000395184 / NM_001025616.3; = p.D535V on NM_031305.3) | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as rs373734849; called by muse, varscan2
- ASH1L | c.5371T>C p.S1791P | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1203988797; called by muse, mutect2
- ATP11A | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232371874, COSV52110708; called by muse, mutect2
- C16orf78 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs201386248; called by muse, mutect2, varscan2
- C2CD3 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | catalogued as rs1189478751, COSV100486470; called by muse, mutect2
- C9orf135 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745462491; called by muse, mutect2, varscan2
- CALCOCO1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV104382172; called by muse, mutect2
- CC2D1B | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs1407698163; called by muse, mutect2
- CD1A | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 103/529 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV56861839; called by muse, mutect2, varscan2
- CEP97 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59127566; called by muse, mutect2, varscan2
- CGGBP1 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1364324411; called by muse, mutect2
- CPNE4 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70190115, COSV70192430; called by muse, mutect2
- DENND5A | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as rs1554925782; called by muse, mutect2, varscan2
- DEPDC4 | c.636T>A p.N212K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV54554476; called by muse, varscan2
- DIS3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV58328340; called by muse, mutect2, varscan2
- DLC1 | c.3919C>A p.L1307M (on ENST00000276297 / NM_001348081.2; = p.L870M on NM_006094.5) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs535433260; called by muse, mutect2, varscan2
- DNAH7 | c.4448C>T p.A1483V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100415083; called by muse, mutect2
- DOCK9 | c.4289_4290dup p.V1431Kfs*19 (on ENST00000376460 / NM_001366676.2; = p.V1432Kfs*19 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | catalogued as rs1303411024; called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.818); catalogued as COSV57516904; called by muse, mutect2
- EPHA3 | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100344906; called by muse, mutect2, varscan2
- FAM114A1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745801701; called by muse, mutect2, varscan2
- FAM122C | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV66194818; called by muse, mutect2
- FOXP3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV66052214; called by muse, mutect2
- FRAS1 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs959684568, COSV53602259; called by muse, mutect2
- GABRG3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61539987; called by muse, mutect2, varscan2
- GAPVD1 | c.3554T>A p.M1185K (on ENST00000394104; = p.M1194K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV52926434; called by mutect2, varscan2
- GP1BA | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs1244043365, COSV56700033; called by muse, mutect2, varscan2
- GPR173 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs1427100063, COSV60236715; called by muse, varscan2
- GRIN3A | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV62454102; called by muse, mutect2
- HSPH1 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60714189; called by muse, mutect2, varscan2
- HTR1A | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502529; called by mutect2, varscan2
- IDNK | c.473del p.P158Qfs*10 | Frame Shift Del (DEL) | VAF 56/200 reads (28%) | catalogued as COSV52890932; called by mutect2, pindel, varscan2
- IGSF3 | c.2847A>G p.P949= (on ENST00000369486 / NM_001007237.3; = p.P969= on NM_001542.4) | Splice Region (SNP) | VAF 30/49 reads (61%) | catalogued as rs752370054; called by muse, mutect2, varscan2
- IPO7 | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as rs1381815089; called by muse, mutect2
- IQCN | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101148681; called by mutect2, varscan2
- ITPR3 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV65413219; called by muse, varscan2
- KDM1B | c.2206G>C p.A736P (on ENST00000449850; = p.A503P on NM_153042.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.21); catalogued as COSV52812672; called by muse, mutect2
- KIAA2026 | c.1795A>G p.T599A | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101198971; called by muse, mutect2
- LARP1 | c.502G>A p.G168S (on ENST00000518297 / NM_033551.3; = p.G91S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.106); catalogued as rs1325211651; called by muse, mutect2, varscan2
- LATS1 | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs777307051; called by muse, mutect2, varscan2
- LHCGR | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1396077178; called by muse, mutect2
- LIMD1 | c.959dup p.E321* | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs756636386; called by mutect2, pindel
- LPAR1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV62688440; called by muse, mutect2
- LRIG2 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV63161638; called by muse, mutect2
- LRP2 | c.5675C>T p.T1892I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV55557153; called by muse, mutect2
- MACF1 | c.21473G>A p.R7158H (on ENST00000372915; = p.R5203H on NM_012090.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV57131516; called by muse, mutect2
- MARF1 | c.3242C>A p.P1081H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60023576; called by muse, mutect2, varscan2
- MCM2 | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1481867506; called by muse, mutect2, varscan2
- MEGF10 | c.2153G>A p.C718Y | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57255015, COSV99175601; called by muse, mutect2
- MEX3C | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1166235105; called by muse, mutect2
- MPPED2 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV63895766; called by muse, mutect2, varscan2
- MRGPRX3 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs1438441396; called by muse, mutect2
- MTTP | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1412530315; called by muse, mutect2
- MUC3A | c.7145C>G p.T2382S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); catalogued as rs201114167; called by muse, mutect2, varscan2
- MUC3A | c.7694C>T p.S2565F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV60216026; called by muse, mutect2, varscan2
- MUC6 | c.148dup p.A50Gfs*108 | Frame Shift Ins (INS) | VAF 38/317 reads (12%) | catalogued as rs760313765; called by mutect2, pindel
- MYH4 | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55122876; called by muse, varscan2
- MYO18A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs560285830; called by muse, mutect2
- NEDD4L | c.1370C>T p.P457L (on ENST00000400345 / NM_001144967.3; = p.P437L on NM_015277.6) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs766146854; called by muse, mutect2, varscan2
- NHS | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.242); catalogued as COSV66276572; called by muse, mutect2, varscan2
- NOX4 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as rs969447848; called by muse, mutect2
- OR2AG1 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56625563; called by muse, mutect2, varscan2
- OR2D2 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs764316567, COSV99079076; called by muse, mutect2, varscan2
- OR5H2 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1006038265; called by muse, mutect2
- OR8K1 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as rs1266382577; called by muse, mutect2
- PALB2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144944814, COSV55168022; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEAK1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1227799088; called by muse, mutect2
- PIGO | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs762788423; called by muse, mutect2, varscan2
- PKDREJ | c.5042G>A p.R1681Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as rs1319017194, COSV53549418; called by muse, mutect2
- PLEKHA4 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374067037, COSV99613323; called by muse, mutect2, varscan2
- POGLUT2 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1344047193, COSV101050827; called by muse, mutect2, varscan2
- QTRT1 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99139060; called by muse, mutect2, varscan2
- RAB19 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1327142718; called by muse, mutect2, varscan2
- RGL3 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs185537653, COSV66508159; called by muse, mutect2, varscan2
- RIPOR2 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.851); catalogued as rs1160219651; called by muse, mutect2, varscan2
- RNF17 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs746275549, COSV55042705, COSV55050126; called by mutect2, varscan2
- RNF38 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV52394470; called by muse, mutect2
- RNF6 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60418830; called by mutect2, varscan2
- S100G | c.54del p.A19Pfs*14 | Frame Shift Del (DEL) | VAF 33/287 reads (11%) | catalogued as COSV63721420; called by mutect2, pindel, varscan2
- SAGE1 | c.2252C>T p.T751I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs782107443; called by muse, mutect2
- SEMA4G | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1261588998; called by muse, mutect2, varscan2
- SEMG2 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65647947; called by muse, mutect2, varscan2
- SEPTIN10 | c.1124del p.K375Rfs*7 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs755586943; called by mutect2, pindel, varscan2
- SMG9 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1568382956, COSV54215284; called by muse, mutect2, varscan2
- SMOX | c.1468A>T p.S490C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1446370390; called by muse, mutect2, varscan2
- SPP1 | c.427A>T p.T143S (on ENST00000395080 / NM_001040058.2; = p.T129S on NM_000582.2) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs199739149; called by muse, mutect2, varscan2
- SREBF2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as rs868058007; called by muse, mutect2
- SREK1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs185065344; called by mutect2, varscan2
- SRR | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV56783862; called by muse, mutect2
- SULT1A1 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs1386277066; called by muse, mutect2, varscan2
- SYTL2 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1480973684; called by muse, mutect2
- TM7SF3 | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100544564; called by muse, mutect2
- TMED1 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1288518725; called by muse, mutect2, varscan2
- TMEM171 | c.755dup p.S253Ffs*20 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | catalogued as rs555350503; called by mutect2, varscan2
- TMEM67 | c.2315T>C p.M772T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as CX070575; called by muse, mutect2
- TRPC6 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 46/542 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs145580926; called by muse, mutect2
- TSC1 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs751362258, COSV100051704, COSV53768986; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TSC1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs118203354, CM992677, COSV53774039; ClinVar: not provided; called by muse, mutect2, varscan2
- ULK4 | c.3431C>T p.A1144V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454005947; called by muse, mutect2, varscan2
- USP18 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as rs945882248; called by muse, mutect2, varscan2
- UTP25 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1224443260; called by muse, mutect2
- WDR35 | c.2024G>A p.R675Q (on ENST00000345530 / NM_001006657.2; = p.R664Q on NM_020779.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs750367225; called by mutect2, varscan2
- WDR7 | c.3692A>G p.D1231G | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs750375531; called by muse, mutect2, varscan2
- ZDHHC11 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as COSV52064857; called by muse, varscan2
- ZNF407 | c.2351A>T p.D784V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99994489; called by mutect2, varscan2
- ZNF507 | c.1428G>T p.E476D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61333766; called by muse, mutect2, varscan2
- ZNF556 | c.888C>G p.Y296* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as COSV100298985, COSV56914619; called by muse, mutect2, varscan2
- ZNF606 | c.1735T>G p.W579G | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV58706111; called by muse, mutect2
- ZNF681 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101267389; called by muse, mutect2
- ABCA3 | c.2459T>G p.L820R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC10 | c.322G>A p.A108T (on ENST00000372530 / NM_001198934.2; = p.A65T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ABCC5 | c.3430C>T p.Q1144* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- ABCD3 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ABHD4 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2
- AC131160.1 | c.726A>T p.Q242H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ACLY | c.2157T>C p.I719= | Splice Region (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- ACO1 | c.1158A>T p.K386N | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by mutect2, varscan2
- ACVR1B | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 8/237 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM7 | c.923dup p.M309Yfs*12 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by pindel, varscan2
- ADAMTS20 | c.4533A>T p.E1511D | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS7 | c.1592dup p.F532Lfs*49 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- ADGRA3 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRE1 | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADGRL4 | c.1227del p.F409Lfs*4 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- AGO2 | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2
- AKAP10 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AL645922.1 | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- ALDH1L1 | c.124dup p.L42Pfs*6 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by pindel, varscan2
- ALDH1L2 | c.279A>T p.E93D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ALK | c.694A>T p.N232Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AMPH | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ANK2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3533G>A p.G1178E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANKRD17 | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ANKRD26 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- ANKRD30A | c.2057A>G p.D686G (on ENST00000611781; = p.D630G on NM_052997.2) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- APOBEC4 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.1); called by muse, mutect2
- AQP8 | c.92A>T p.Y31F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.057); called by mutect2, varscan2
- ARAP3 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ARFGEF1 | c.2217A>T p.Q739H | Missense Mutation (SNP) | VAF 11/385 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ARHGAP20 | c.3433C>T p.P1145S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.2827_2828insA p.L943Hfs*5 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.357G>A p.W119* (on ENST00000409202 / NM_001007231.3; = p.W112* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- ARHGAP32 | c.3340C>T p.P1114S (on ENST00000310343 / NM_001378025.1; = p.P765S on NM_014715.4) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- ARHGEF10 | c.1331dup p.L444Ffs*5 (on ENST00000398564; = p.L419Ffs*5 on NM_014629.4) | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- ARSK | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- ASB14 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ASH1L | c.8894A>G p.N2965S (on ENST00000368346 / NM_001366177.2; = p.N2960S on NM_018489.3) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by mutect2, varscan2
- ATOH8 | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP6V0A1 | c.1488dup p.N497Efs*23 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, varscan2
- ATP8B4 | c.1530dup p.K511* | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, varscan2
- BAHD1 | c.1760del p.R587Pfs*33 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- BCAT1 | c.445del p.Q149Kfs*39 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | called by mutect2, pindel, varscan2
- BCORL1 | c.1911C>A p.N637K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.712); called by mutect2, varscan2
- BCORL1 | c.5017G>A p.G1673R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2
- BICRAL | c.375T>A p.Y125* | Nonsense Mutation (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- BLOC1S6 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); called by muse, mutect2
- BMP7 | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BRD2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- BRINP2 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- BRSK1 | c.583dup p.H195Pfs*9 | Frame Shift Ins (INS) | VAF 25/191 reads (13%) | called by mutect2, pindel, varscan2
- BTLA | c.404-1G>T p.X135_splice | Splice Site (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- BTN2A1 | c.173dup p.N58Kfs*3 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- BUD13 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- C14orf119 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- C17orf64 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- C19orf44 | c.1277A>T p.E426V | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QTNF2 | c.38del p.A13Vfs*31 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- C1orf54 | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf194 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.306); called by muse, mutect2
- C6orf118 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- C6orf47 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C8A | c.506A>T p.D169V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA1F | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- CAPN11 | c.1430T>G p.F477C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by mutect2, varscan2
- CASP1 | c.652T>A p.F218I (on ENST00000436863 / NM_033292.4; = p.F197I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CATSPERD | c.1987dup p.W663Lfs*46 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by pindel, varscan2
- CBWD2 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- CCDC171 | c.1536T>A p.H512Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by mutect2, varscan2
- CCNI | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.036); called by muse, mutect2
- CELSR2 | c.3068T>C p.L1023P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP126 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2
- CEP41 | c.945A>T p.E315D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CERKL | c.767T>A p.V256D (on ENST00000339098 / NM_001030311.2; = p.V230D on NM_201548.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP251 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 313/1992 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by mutect2, varscan2
- CFAP43 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, varscan2
- CHAF1A | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CHD3 | c.3419dup p.L1141Pfs*9 | Frame Shift Ins (INS) | VAF 16/152 reads (11%) | called by pindel, varscan2
- CLCC1 | c.1525T>A p.S509T (on ENST00000356970 / NM_001377464.1; = p.S459T on NM_015127.5) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CLYBL | c.606dup p.G203Wfs*14 | Frame Shift Ins (INS) | VAF 20/178 reads (11%) | called by mutect2, pindel, varscan2
- CNOT1 | c.2677A>G p.R893G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- COG7 | c.479G>C p.S160T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL21A1 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A5 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- CPNE3 | c.56del p.L19Wfs*5 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | called by mutect2, varscan2
- CREB3L3 | c.595dup p.A199Gfs*21 | Frame Shift Ins (INS) | VAF 82/226 reads (36%) | called by mutect2, varscan2
- CRLF2 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- CTR9 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.166); called by muse, varscan2
- CYP4X1 | c.90dup p.K31* | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- DCLK1 | c.1412del p.G471Efs*25 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- DCTN2 | c.883A>C p.K295Q (on ENST00000548249 / NM_001261413.2; = p.K300Q on NM_006400.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- DCX | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- DDAH1 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- DDX20 | c.1529dup p.N510Kfs*2 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- DENND2C | c.446T>A p.L149Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by mutect2, varscan2
- DISP1 | c.1465T>C p.F489L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.23); called by mutect2, varscan2
- DLG5 | c.4944_4945insA p.G1649Rfs*21 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by pindel, varscan2
- DNAH11 | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAH2 | c.2218A>G p.I740V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- DNAH2 | c.10937T>A p.I3646N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.8616dup p.L2873Tfs*5 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- DNAH7 | c.4736C>A p.S1579Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2
- DNAJC14 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNMT1 | c.1187T>A p.F396Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- DOCK10 | c.4718A>T p.N1573I | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- DOCK8 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, varscan2
- DSCAML1 | c.1472C>T p.A491V (on ENST00000321322; = p.A431V on NM_020693.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DTX3 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DYSF | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, varscan2
- DZIP1 | c.1718T>C p.V573A (on ENST00000347108; = p.V554A on NM_014934.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- EFHB | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- EIF4ENIF1 | c.2438T>A p.L813H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EIF5B | c.1240_1241dup p.A415Kfs*45 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, varscan2
- EPG5 | c.6382G>A p.A2128T | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2
- EPHB6 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ERBIN | c.2196A>T p.E732D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); called by mutect2, varscan2
- ERCC3 | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- ERCC4 | c.2566_2567insT p.P856Lfs*16 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ERG | c.1298A>C p.Q433P (on ENST00000398919 / NM_001243428.1; = p.Q409P on NM_004449.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, varscan2
- ERICH6 | c.1691del p.G564Afs*12 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- ETV4 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- EXTL3 | c.2369A>T p.N790I | Missense Mutation (SNP) | VAF 28/610 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FAM13A | c.364A>G p.R122G | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FANCA | c.733A>T p.R245W | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FAT1 | c.8507C>T p.A2836V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAT1 | c.7529T>A p.L2510Q | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- FAT1 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.4905A>G p.I1635M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAT4 | c.6981dup p.E2328Rfs*29 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by pindel, varscan2
- FBXO38 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FGD1 | c.2097A>T p.K699N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FGD6 | c.2905T>G p.Y969D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FKBP14 | c.50del p.L17* | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- FKBP15 | c.3304C>A p.P1102T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); called by muse, mutect2
- FLOT1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLT3 | c.2152T>C p.F718L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by mutect2, varscan2
- FN1 | c.6009dup p.N2004Qfs*26 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by pindel, varscan2
- FOXM1 | c.816C>G p.Y272* | Nonsense Mutation (SNP) | VAF 87/187 reads (47%) | called by muse, mutect2, varscan2
- FREM2 | c.7262G>A p.C2421Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FSIP2 | c.16202A>C p.D5401A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- FUBP3 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- GBX1 | c.540A>T p.A180= | Splice Region (SNP) | VAF 28/532 reads (5%) | called by muse, mutect2
- GDF2 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- GLDN | c.1084T>A p.F362I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2
- GLE1 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GLIS3 | c.93G>T p.M31I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- GLRX5 | c.403del p.V135Wfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- GPATCH2 | c.495A>C p.K165N | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR137B | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 5/128 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRIK4 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- GRIPAP1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM8 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRPR | c.91A>G p.N31D | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSTCD | c.1534G>A p.A512T (on ENST00000360505 / NM_001031720.3; = p.A425T on NM_024751.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GTF2H1 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GTF3C3 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HADHB | c.107dup p.A37Sfs*36 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- HEATR5A | c.6124A>T p.K2042* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | called by mutect2, varscan2
- HECTD1 | c.6398T>C p.V2133A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- HEG1 | c.368dup p.N123Kfs*43 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- HIVEP3 | c.2264A>G p.K755R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); called by muse, mutect2
- HMBOX1 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- HNRNPH2 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- HSD17B7 | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- HTR2B | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HTR3A | c.1397T>A p.I466N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HUWE1 | c.12238T>A p.L4080M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- IFNAR2 | c.44dup p.L15Ffs*16 | Frame Shift Ins (INS) | VAF 49/273 reads (18%) | called by mutect2, pindel, varscan2
- IGKV2D-29 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 47/477 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGSF1 | c.3341G>A p.G1114E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF3 | c.1310C>T p.A437V (on ENST00000369486 / NM_001007237.3; = p.A457V on NM_001542.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- IPCEF1 | c.605del p.N202Ifs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.2626A>G p.K876E | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- IRAK2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IREB2 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2
- IRF2BP2 | c.1690T>C p.W564R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- IST1 | c.1033C>T p.P345S (on ENST00000535424 / NM_001270976.1; = p.C330= on NM_014761.4) | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGA2 | c.604del p.L202Wfs*3 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- ITGAD | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK1 | c.3629C>A p.A1210E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KANSL3 | c.2339C>T p.A780V (on ENST00000666923 / NM_001349262.2; = p.A754V on NM_001115016.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6A | c.3748C>A p.P1250T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by mutect2, varscan2
- KCNE4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- KCNH1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2
- KCNK12 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5A | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- KDM5C | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by mutect2, varscan2
- KIAA0232 | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1109 | c.2543_2544del p.K848Rfs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- KIAA1217 | c.2864G>T p.S955I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- KIRREL2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL5 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- KMT2D | c.15260G>A p.G5087E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.15125C>T p.A5042V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.922); called by muse, varscan2
- KMT2D | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KNTC1 | c.1407A>T p.E469D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- KRT40 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- KRTAP10-9 | c.814T>C p.C272R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- KY | c.801T>G p.H267Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- LAMA2 | c.8480A>G p.Y2827C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, varscan2
- LAMB2 | c.2099dup p.S701Kfs*5 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- LAPTM5 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2
- LARP1 | c.3027dup p.K1010Qfs*13 (on ENST00000518297 / NM_033551.3; = p.K933Qfs*13 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by pindel, varscan2
- LCK | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LCT | c.2248A>T p.I750L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- LGALS9C | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- LPA | c.5930A>T p.E1977V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- LPP | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LSM1 | c.165dup p.Y56Ifs*3 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- MACF1 | c.4762G>A p.G1588S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- MAP4 | c.812A>C p.E271A | Missense Mutation (SNP) | VAF 21/483 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2
- MAPK9 | c.981dup p.A328Rfs*12 | Frame Shift Ins (INS) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- MARCHF6 | c.1387A>T p.N463Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- MBD2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- MCCC1 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MCM3 | c.2354A>G p.D785G (on ENST00000229854 / NM_001366374.2; = p.D775G on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2
- MCM3 | c.2087A>G p.E696G (on ENST00000229854 / NM_001366374.2; = p.E686G on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by mutect2, varscan2
- MDC1 | c.3340A>G p.R1114G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2
- MED12L | c.4854dup p.D1619* | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- MEFV | c.2090dup p.N697Kfs*2 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | called by pindel, varscan2
- MICAL1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIEF1 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | called by muse, varscan2
- MLXIP | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MNT | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by mutect2, varscan2
- MSH5 | c.2489C>A p.A830D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MSH6 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- MTBP | c.1538dup p.Y513* | Nonsense Mutation (INS) | VAF 17/140 reads (12%) | called by mutect2, pindel, varscan2
- MUC16 | c.17882T>A p.L5961H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); called by mutect2, varscan2
- MYBPC2 | c.388dup p.D130Gfs*16 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- MYH15 | c.3745C>T p.Q1249* | Nonsense Mutation (SNP) | VAF 27/516 reads (5%) | called by muse, mutect2
- MYH9 | c.5058G>T p.Q1686H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYOM1 | c.2634A>T p.K878N | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- N4BP2L2 | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by mutect2, varscan2
- NAPSA | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- NCL | c.2109A>T p.Q703H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NEB | c.18692A>T p.E6231V | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- NEB | c.10774A>T p.S3592C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEU2 | c.1044dup p.F350Vfs*9 | Frame Shift Ins (INS) | VAF 134/619 reads (22%) | called by mutect2, varscan2
- NKG7 | c.145dup p.D49Gfs*115 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- NLRC3 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NOCT | c.1079dup p.Y361Ifs*23 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- NRP2 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- NUDT5 | c.364dup p.D122Gfs*28 | Frame Shift Ins (INS) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- NUP155 | c.3410A>T p.D1137V (on ENST00000231498 / NM_153485.3; = p.D1078V on NM_004298.4) | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- OAS3 | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by mutect2, varscan2
- OCRL | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPA3 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2
- OPALIN | c.10dup p.S4Ffs*58 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- OPRL1 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- OR1N2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- OR2B6 | c.170_171insA p.M59Hfs*53 | Frame Shift Ins (INS) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- OR2F1 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2
- OR52E6 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR7A5 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2
- OR8B12 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); called by muse, varscan2
- P4HA1 | c.1203A>G p.I401M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PALLD | c.1502-1G>A p.X501_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PAN2 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | called by muse, varscan2
- PDE3A | c.1618A>G p.S540G | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PDGFRA | c.230A>C p.N77T | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PI4KB | c.1520+1G>C p.X507_splice (on ENST00000368873 / NM_001369623.1; = p.X519_splice on NM_002651.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 69/1134 reads (6%) | called by muse, mutect2
- PJA2 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- PLCH1 | c.2507A>T p.Y836F (on ENST00000340059 / NM_001130960.2; = p.Y848F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, varscan2
- PNMA5 | c.1138dup p.Q380Pfs*20 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- POP1 | c.2509del p.Q837Sfs*4 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- POU4F2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PPARGC1A | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); called by muse, mutect2
- PREB | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PRELID2 | c.395dup p.N132Kfs*42 (on ENST00000334744 / NM_182960.4; = p.N91Kfs*42 on NM_138492.6) | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- PRKAG3 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKD1 | c.1589G>T p.R530M | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, varscan2
- PROS1 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMA7 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- PSPC1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PTMS | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.812); called by mutect2, varscan2
- PTPN6 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- RAB11FIP2 | c.1315A>C p.S439R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.021); called by muse, varscan2
- RAB11FIP3 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); called by muse, mutect2
- RAD23B | c.531del p.F177Lfs*9 | Frame Shift Del (DEL) | VAF 2/22 reads (9%) | called by pindel, varscan2
- RAD50 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RALY | c.38A>T p.K13M | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAPGEF2 | c.3434A>G p.H1145R | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- RGL1 | c.186A>T p.E62D (on ENST00000360851 / NM_001297672.2; = p.E97D on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- RHBDL3 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RILPL2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- RIMS1 | c.54dup p.M19Hfs*56 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- RNASE4 | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RNASEL | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- RPL5 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2
- RPS18 | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, varscan2
- RPTN | c.2111G>A p.W704* | Nonsense Mutation (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- RRH | c.913A>T p.M305L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXYLT1 | c.576dup p.L193Tfs*12 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- SCARB1 | c.559dup p.L187Pfs*24 | Frame Shift Ins (INS) | VAF 36/218 reads (17%) | called by mutect2, pindel, varscan2
- SCN7A | c.1581T>A p.Y527* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- SEC24C | c.49del p.Q17Sfs*210 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, varscan2
- SEMA4F | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, varscan2
- SEMA6A | c.2763dup p.T922Hfs*19 | Frame Shift Ins (INS) | VAF 12/116 reads (10%) | called by mutect2, pindel
- SERGEF | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SERINC5 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2
- SH2B1 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SHC3 | c.1061dup p.F355Lfs*3 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | called by mutect2, varscan2
- SHPK | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- SHROOM3 | c.4505A>G p.E1502G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by mutect2, varscan2
- SIK3 | c.2905C>T p.Q969* (on ENST00000445177 / NM_001366686.2; = p.Q927* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/115 reads (5%) | called by muse, mutect2
- SLC25A24 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SLC35F1 | c.1045G>C p.G349R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC41A1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC8A2 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- SMARCC1 | c.2444dup p.N815Kfs*2 | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, varscan2
- SNF8 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOBP | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SORBS2 | c.908dup p.S304Ifs*8 (on ENST00000284776 / NM_021069.5; = p.S397Ifs*7 on NM_003603.6) | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by pindel, varscan2
- SOS1 | c.2511-2A>C p.X837_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- SPEF2 | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- SPI1 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SPTB | c.6122T>C p.V2041A | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SPTBN1 | c.4904A>G p.Q1635R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- SPTBN2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRF | c.690dup p.T231Hfs*12 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- SSH1 | c.1806dup p.Q603Afs*31 | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | called by mutect2, pindel
- STAT2 | c.1476dup p.W493Lfs*38 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- STAT2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.581); called by muse, mutect2
- STK36 | c.2642dup p.L881Ffs*31 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | called by mutect2, pindel, varscan2
- STX3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- STX5 | c.355del p.A119Qfs*17 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel
- SUMF2 | c.193G>A p.D65N (on ENST00000652303; = p.D46N on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); called by muse, mutect2
- SUPT6H | c.4373T>C p.I1458T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- SYNE1 | c.19793T>C p.L6598P (on ENST00000367255 / NM_182961.4; = p.L6527P on NM_033071.3) | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNE1 | c.14713G>A p.A4905T (on ENST00000367255 / NM_182961.4; = p.A4834T on NM_033071.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYT11 | c.388dup p.E130Gfs*39 | Frame Shift Ins (INS) | VAF 24/185 reads (13%) | called by mutect2, pindel, varscan2
- TAF11 | c.249dup p.L84Tfs*17 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- TAS2R8 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TASOR2 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by mutect2, varscan2
- TBC1D15 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); called by muse, mutect2
- TCF20 | c.1707dup p.R570Qfs*5 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by pindel, varscan2
- TENT2 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TEX15 | c.6886C>T p.P2296S (on ENST00000256246; = p.P2679S on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGM6 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIGIT | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- TIMELESS | c.3063G>A p.W1021* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- TLR7 | c.2120G>A p.S707N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TM9SF3 | c.1548G>C p.W516C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMLHE | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2
- TMOD2 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNFRSF13B | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TNS3 | c.3713dup p.L1238Ffs*17 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- TOM1L2 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TRDV3 | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TRIM33 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2
- TRIM5 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- TRIM58 | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- TRIO | c.2194dup p.E732Gfs*15 | Frame Shift Ins (INS) | VAF 28/180 reads (16%) | called by pindel, varscan2
- TRPS1 | c.3460dup p.S1154Ffs*8 (on ENST00000220888 / NM_001330599.2; = p.S1167Ffs*8 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- TRPV5 | c.1613T>C p.L538P | Missense Mutation (SNP) | VAF 174/838 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TRRAP | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.041); called by muse, mutect2
- TSGA13 | c.332A>C p.Q111P | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TTLL1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TTN | c.80886dup p.P26963Tfs*4 (on ENST00000591111; = p.P19539Tfs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- TTN | c.56243A>T p.D18748V (on ENST00000591111; = p.D11324V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- UBR2 | c.453T>A p.C151* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- UBR4 | c.4748dup p.N1583Kfs*23 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- UBXN7 | c.970dup p.S324Ffs*4 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- UGT2B17 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- USB1 | c.516dup p.L173Afs*2 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- USH2A | c.13910dup p.P4638Sfs*45 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- USP31 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- UVRAG | c.1149A>T p.R383S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- VCAN | c.8626T>C p.F2876L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VCL | c.965T>A p.L322Q | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by mutect2, varscan2
- VIRMA | c.5354C>T p.A1785V | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- VPS52 | c.694dup p.V232Gfs*46 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- WSCD1 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- YLPM1 | c.2684C>A p.A895E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by mutect2, varscan2
- YWHAE | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZBTB39 | c.965T>G p.L322R | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ZBTB39 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.306); called by muse, mutect2
- ZC3H12B | c.510del p.R171Efs*14 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9330dup p.G3111Rfs*80 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ZFP2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.562); called by muse, varscan2
- ZNF112 | c.1225C>A p.H409N (on ENST00000337401 / NM_001083335.2; = p.H403N on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ZNF12 | c.497A>T p.D166V (on ENST00000405858 / NM_016265.4; = p.D128V on NM_006956.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by mutect2, varscan2
- ZNF134 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF134 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF134 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF160 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF404 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF41 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF562 | c.1026dup p.P343Tfs*3 (on ENST00000453372 / NM_001130032.2; = p.P271Tfs*3 on NM_017656.4) | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, varscan2
- ZNF578 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF670 | c.1099T>G p.C367G | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF766 | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ZNF77 | c.720T>G p.H240Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- ZNF782 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 152/1186 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF782 | c.1205C>G p.A402G | Missense Mutation (SNP) | VAF 41/515 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); called by muse, mutect2
- ZNF804B | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- ZNF85 | c.228A>G p.T76= | Splice Region (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ZNFX1 | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); called by muse, mutect2
- ZP3 | c.977A>T p.D326V (on ENST00000394857 / NM_001110354.2; = p.D275V on NM_007155.6) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZSCAN21 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, varscan2
- ADGRG2 | c.327C>T p.I109= (on ENST00000379869 / NM_001079858.3; = p.I106= on NM_005756.4) | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- AMFR | c.933G>A p.R311= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- APLP2 | c.168T>C p.C56= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- ASIC4 | c.522C>T p.A174= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs777630389; called by muse, mutect2, varscan2
- ATP2B1 | c.1062G>A p.L354= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as rs775597893; called by muse, mutect2, varscan2
- BAALC | c.426C>T p.T142= (on ENST00000297574 / NM_001364874.1; = p.T107= on NM_024812.3) | Silent (SNP) | VAF 13/237 reads (5%) | called by muse, mutect2
- BACH2 | c.2502A>G p.E834= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- BARHL1 | c.90G>A p.G30= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- BCL11A | c.897A>G p.P299= (on ENST00000335712 / NM_001365609.1; = p.P333= on NM_018014.4) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs367763332; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCL2L12 | c.426G>A p.L142= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- BMP1 | c.978G>A p.L326= | Silent (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- BSPRY | c.702C>T p.I234= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs369636312; called by mutect2, varscan2
- C16orf70 | c.565C>T p.L189= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- C1orf56 | c.828T>A p.S276= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- CAD | c.570C>A p.I190= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1302128955; called by muse, mutect2, varscan2
- CAMKK2 | c.1137A>C p.T379= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- CBLL2 | c.396T>A p.A132= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- CCHCR1 | c.1699C>T p.L567= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1411670658; called by mutect2, varscan2
- CD68 | c.663A>G p.G221= | Silent (SNP) | VAF 34/299 reads (11%) | called by muse, mutect2, varscan2
- CDC14A | c.918T>A p.A306= | Silent (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- CDH2 | c.1140A>T p.P380= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2
- CFAP70 | c.183T>C p.T61= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1456639517; called by muse, mutect2, varscan2
- CHD6 | c.6702A>T p.P2234= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- CHD6 | c.3699C>T p.V1233= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- CLCN1 | c.1263C>T p.R421= | Silent (SNP) | VAF 49/760 reads (6%) | catalogued as rs745472087; ClinVar: likely benign; called by muse, mutect2
- CNOT10 | c.2088T>A p.T696= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- COA7 | c.118C>T p.L40= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- COL7A1 | c.8673C>T p.R2891= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.10825C>T p.L3609= (on ENST00000297405 / NM_001363185.1; = p.L3440= on NM_052900.3) | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV99850970; called by muse, mutect2
- CTSG | c.435C>T p.A145= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV53535191; called by muse, mutect2, varscan2
- DCDC2 | c.414G>A p.P138= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs145717239; called by muse, mutect2, varscan2
- DKK4 | c.348T>C p.T116= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs1022411330; called by muse, mutect2, varscan2
- DNAH9 | c.11271G>A p.Q3757= | Silent (SNP) | VAF 66/316 reads (21%) | called by muse, varscan2
- DOCK3 | c.1791G>A p.Q597= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV56541445; called by muse, mutect2, varscan2
- DOCK7 | c.4338A>G p.K1446= (on ENST00000635253 / NM_001367561.1; = p.K1415= on NM_033407.3) | Silent (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2, varscan2
- DOCK8 | c.3468G>A p.Q1156= | Silent (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- EOMES | c.936C>T p.H312= | Silent (SNP) | VAF 54/280 reads (19%) | called by muse, mutect2, varscan2
- FAXDC2 | c.858C>T p.C286= | Silent (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- FFAR3 | c.663G>A p.R221= | Silent (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- FGD4 | c.2169C>T p.D723= | Silent (SNP) | VAF 30/105 reads (29%) | called by muse, mutect2, varscan2
- FN1 | c.5445C>T p.S1815= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- GATAD2B | c.1758G>A p.S586= | Silent (SNP) | VAF 37/1308 reads (3%) | catalogued as rs368022295; called by muse, mutect2
- GPATCH3 | c.696C>T p.Y232= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as rs149060380; called by muse, varscan2
- GPR179 | c.5730A>G p.E1910= (on ENST00000621958; = p.E1909= on NM_001004334.4) | Silent (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- GPRASP1 | c.96C>T p.V32= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100851077; called by muse, mutect2, varscan2
- GRIK3 | c.1938G>A p.T646= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs144959883, COSV66138584; called by mutect2, varscan2
- GRM1 | c.822G>A p.L274= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- GTF3C3 | c.1653T>A p.G551= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- HAP1 | c.1927C>T p.L643= (on ENST00000310778 / NM_001367460.1; = p.L591= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- HDAC9 | c.45T>G p.P15= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV101288044; called by muse, mutect2
- HHATL | c.660G>C p.G220= | Silent (SNP) | VAF 41/209 reads (20%) | called by mutect2, varscan2
- IGSF5 | c.756A>G p.S252= | Silent (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2
- IL7R | c.1086A>T p.G362= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- INPP5B | c.241C>T p.L81= | Silent (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- INSR | c.2802C>T p.G934= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ITGB7 | c.45C>T p.S15= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- KIAA0753 | c.696A>G p.K232= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- KLHL11 | c.1251A>T p.P417= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- KMT5B | c.1183C>A p.R395= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV58569875; called by muse, mutect2
- KSR2 | c.402C>T p.Y134= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs759965853, COSV60383868; called by muse, mutect2, varscan2
- LBHD1 | c.15A>T p.P5= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- LRRC17 | c.252G>A p.L84= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- M1AP | c.1087C>T p.L363= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV51847638; called by muse, mutect2, varscan2
- MAGI2 | c.1332C>T p.D444= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs368034452; called by muse, mutect2, varscan2
- MID1 | c.948G>A p.A316= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs769379244; ClinVar: benign; called by mutect2, varscan2
- MUC16 | c.15417C>A p.S5139= | Silent (SNP) | VAF 28/333 reads (8%) | called by muse, mutect2
- NAV1 | c.3960G>A p.K1320= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- NEDD4 | c.2148T>C p.L716= (on ENST00000508342 / NM_001284338.1; = p.L297= on NM_006154.4) | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- NIPAL4 | c.495A>G p.A165= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- OR13F1 | c.598C>T p.L200= | Silent (SNP) | VAF 16/269 reads (6%) | catalogued as COSV58252035; called by muse, mutect2
- OR6Y1 | c.798T>C p.R266= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- PBRM1 | c.2925A>T p.P975= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- PCSK2 | c.573C>T p.S191= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- PDE4A | c.1324C>T p.L442= (on ENST00000380702 / NM_001111307.2; = p.L203= on NM_006202.3) | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- PLEKHM3 | c.108T>C p.V36= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, varscan2
- PSMB8 | c.6G>A p.A2= | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.1416C>A p.T472= | Silent (SNP) | VAF 32/94 reads (34%) | called by muse, varscan2
- RAD9B | c.777T>A p.A259= | Silent (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- RBFOX2 | c.330A>G p.T110= (on ENST00000438146 / NM_001349995.2; = p.T40= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/446 reads (4%) | called by muse, mutect2
- REXO4 | c.558A>T p.P186= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- RGS12 | c.918G>A p.P306= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs201719575; called by mutect2, varscan2
- RHD | c.762A>G p.S254= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- RHNO1 | c.9C>G p.P3= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ROBO1 | c.3231G>A p.Q1077= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- RORA | c.276C>T p.G92= (on ENST00000335670 / NM_134261.3; = p.G117= on NM_002943.3) | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- SESN1 | c.600A>G p.V200= (on ENST00000356644 / NM_001199933.1; = p.V259= on NM_014454.3) | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs1301972525, COSV57420750; called by muse, mutect2, varscan2
- SGSM1 | c.3141T>C p.Y1047= (on ENST00000400359 / NM_001039948.4; = p.Y986= on NM_133454.3) | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2, varscan2
- SH3GL2 | c.651A>G p.A217= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- SLC25A35 | c.663G>A p.L221= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- SLC30A6 | c.156C>T p.C52= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- SLITRK2 | c.912G>A p.P304= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs377471915; called by muse, mutect2
- SLITRK3 | c.2508T>C p.H836= | Silent (SNP) | VAF 8/101 reads (8%) | called by mutect2, varscan2
- SLX4 | c.123T>G p.G41= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- SMG8 | c.2391T>A p.P797= | Silent (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- SP110 | c.543G>A p.L181= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- SPTLC1 | c.858C>T p.G286= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- TDRD5 | c.1443C>T p.I481= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- TECTA | c.705G>A p.E235= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- TIAM1 | c.1476A>G p.K492= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TMPRSS7 | c.1108T>C p.L370= (on ENST00000452346; = p.L244= on NM_001042575.2) | Silent (SNP) | VAF 58/660 reads (9%) | called by muse, mutect2
- TNC | c.4263C>T p.I1421= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- TNKS | c.1467A>G p.K489= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- TRIM25 | c.1632C>T p.R544= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV57544089; called by muse, mutect2, varscan2
- TRMT12 | c.345G>A p.V115= | Silent (SNP) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- TRPM2 | c.930G>A p.S310= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs36007753, COSV100309297; called by muse, varscan2
- TTLL6 | c.2001C>T p.A667= (on ENST00000393382 / NM_001130918.3; = p.A360= on NM_173623.3) | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- VPS13D | c.6387G>A p.K2129= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- VWA2 | c.774A>T p.P258= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1563T>C p.C521= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- ZFP57 | c.681G>T p.G227= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- ZFP69B | c.987T>C p.H329= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- ZFY | c.2253C>T p.S751= | Silent (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- ZFYVE9 | c.354A>G p.R118= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ZHX2 | c.1965C>T p.P655= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV58713054; called by mutect2, varscan2
- ZMYM3 | c.4023C>T p.R1341= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ZNF101 | c.1134C>T p.C378= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs1333925848; called by muse, mutect2, varscan2
- ZNF195 | c.747T>C p.C249= (on ENST00000399602 / NM_001130520.3; = p.C177= on NM_007152.5) | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ZNF462 | c.1902G>A p.G634= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs759582171; called by muse, mutect2, varscan2
- ZNF484 | c.2418C>T p.C806= | Silent (SNP) | VAF 32/495 reads (6%) | called by muse, mutect2
- ZNF700 | c.210G>A p.Q70= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99583468; called by muse, mutect2, varscan2
- ZNF746 | c.423G>A p.K141= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- ZNFX1 | c.411G>A p.Q137= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- AL031659.1 | chr20:37168160 G>A | 5'Flank (SNP) | VAF 21/63 reads (33%) | catalogued as rs1165788573, COSV54117128; called by muse, mutect2, varscan2
- AL109984.1 | n.186+5484dup | Intron (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- FBH1 | c.1+4761G>A | Intron (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- LPAL2 | n.42G>C | RNA (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- PLA2G12B | c.-2G>T | 5'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- RAPGEF5 | chr7:22193981 A>T | 5'Flank (SNP) | VAF 36/238 reads (15%) | called by muse, varscan2
- UBE2V2 | c.*1T>C | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- UGT1A6 | c.862-23330dup | Intron (INS) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
